Somatic mutation profile of tumor specimen TCGA-09-2044-01B (aliquot TCGA-09-2044-01B-01W-0799-08) from TCGA case TCGA-09-2044, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIB; Tumor grade: G3; Age at diagnosis: 77.3 years (28,231 days).
Specimen TCGA-09-2044-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 55c763d5-eed4-42cf-979f-d216fbfb2df1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-09-2044-10A (Blood Derived Normal), aliquot TCGA-09-2044-10A-01D-0704-01; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4f6fa018-bd87-4175-946d-d6d5c15bb16c

The open-access MAF lists 122 somatic variants for this specimen: 100 protein-altering or splice-affecting, 19 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 76, Silent 19, Frame Shift Del 8, Nonsense Mutation 6, Splice Site 4, Splice Region 3, In Frame Del 2, Intron 2, 3'Flank 1, Nonstop Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PACS1 | c.607C>T p.R203W | Missense Mutation (SNP) | VAF 199/466 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs398123009, CM1211547, COSV57698895; ClinVar: pathogenic; called by muse, varscan2
- TP53 | c.560-1_583del p.X187_splice | Splice Site (DEL) | VAF 26/59 reads (44%) | hotspot (GDC flag); called by mutect2, pindel, varscan2
- ADGRV1 | c.10156A>T p.T3386S | Missense Mutation (SNP) | VAF 203/292 reads (70%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as COSV101316086; called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.3751G>C p.E1251Q | Missense Mutation (SNP) | VAF 9/144 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99783560; called by muse, mutect2
- ASPH | c.1129G>C p.A377P | Missense Mutation (SNP) | VAF 146/408 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV65245971; called by muse, mutect2, varscan2
- B4GALT5 | c.338C>A p.T113N | Missense Mutation (SNP) | VAF 249/625 reads (40%) | SIFT tolerated (0.27); PolyPhen benign (0.042); catalogued as COSV65494546; called by muse, mutect2, varscan2
- BDKRB1 | c.595C>A p.H199N | Missense Mutation (SNP) | VAF 30/52 reads (58%) | SIFT tolerated (0.41); PolyPhen benign (0.007); catalogued as COSV53706722; called by muse, mutect2, varscan2
- BPIFB2 | c.444T>A p.D148E | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT tolerated (0.38); PolyPhen benign (0.005); catalogued as COSV99401443; called by muse, mutect2, varscan2
- BPIFB2 | c.445G>A p.G149S | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.038); catalogued as COSV99401445; called by muse, mutect2, varscan2
- BPTF | c.3136G>C p.V1046L | Missense Mutation (SNP) | VAF 53/151 reads (35%) | SIFT tolerated (0.28); PolyPhen benign (0.001); catalogued as COSV58842430; called by muse, mutect2, varscan2
- C9orf72 | c.1372G>C p.G458R | Missense Mutation (SNP) | VAF 35/107 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66163734, COSV66163764; called by muse, mutect2, varscan2
- CD101 | c.1436G>T p.S479I | Missense Mutation (SNP) | VAF 20/215 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.091); catalogued as COSV56716157; called by muse, mutect2, varscan2
- CGA | c.287G>C p.G96A | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT tolerated (0.55); PolyPhen benign (0.093); catalogued as COSV63644744; called by muse, mutect2, varscan2
- COL7A1 | c.7052G>C p.G2351A | Missense Mutation (SNP) | VAF 9/9 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60398879; called by muse, mutect2, varscan2
- CR2 | c.295G>T p.G99* | Nonsense Mutation (SNP) | VAF 26/149 reads (17%) | catalogued as COSV100889660, COSV65508724; called by muse, mutect2, varscan2
- CTNNB1 | c.1955-2A>G p.X652_splice | Splice Site (SNP) | VAF 82/816 reads (10%) | catalogued as COSV62703256; called by muse, mutect2
- CYP2A6 | c.657C>A p.L219= | Splice Region (SNP) | VAF 24/96 reads (25%) | catalogued as COSV56536216; called by muse, mutect2, varscan2
- CYP2C19 | c.1097T>A p.L366Q | Missense Mutation (SNP) | VAF 221/803 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.875); catalogued as COSV64908617; called by muse, mutect2, varscan2
- CYP7B1 | c.1277C>T p.T426I | Missense Mutation (SNP) | VAF 27/76 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.872); catalogued as COSV59593278; called by muse, mutect2, varscan2
- DDIAS | c.179C>T p.S60F | Missense Mutation (SNP) | VAF 106/143 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV61272759; called by muse, mutect2, varscan2
- DNTTIP1 | c.478G>T p.G160* | Nonsense Mutation (SNP) | VAF 80/192 reads (42%) | catalogued as COSV65460106; called by muse, varscan2
- DSN1 | c.354A>C p.T118= | Splice Region (SNP) | VAF 117/347 reads (34%) | catalogued as COSV65519160, COSV65519754; called by muse, mutect2, varscan2
- EIF4A1 | c.839A>G p.N280S | Missense Mutation (SNP) | VAF 68/90 reads (76%) | SIFT deleterious (0.04); PolyPhen benign (0.209); catalogued as COSV51511545; called by muse, mutect2, varscan2
- FAM199X | c.1093T>C p.F365L | Missense Mutation (SNP) | VAF 147/179 reads (82%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as COSV55434139; called by muse, mutect2, varscan2
- FAT3 | c.2609T>G p.V870G | Missense Mutation (SNP) | VAF 85/115 reads (74%) | SIFT deleterious (0); PolyPhen possibly damaging (0.533); catalogued as COSV53146082; called by muse, mutect2, varscan2
- FCHO2 | c.1523G>T p.S508I | Missense Mutation (SNP) | VAF 51/66 reads (77%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.928); catalogued as COSV59275260; called by muse, mutect2, varscan2
- FCHSD1 | c.926T>C p.V309A | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.214); catalogued as COSV71301513; called by muse, mutect2
- FRMPD3 | c.2218G>A p.V740M | Missense Mutation (SNP) | VAF 28/272 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99346437; called by muse, mutect2, varscan2
- GLRA3 | c.1003G>A p.A335T | Missense Mutation (SNP) | VAF 141/338 reads (42%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.939); catalogued as COSV56866317, COSV56871195; called by muse, mutect2, varscan2
- GPATCH2L | c.1062A>T p.K354N | Missense Mutation (SNP) | VAF 67/170 reads (39%) | SIFT tolerated (0.46); PolyPhen benign (0.139); catalogued as COSV55050024; called by muse, mutect2, varscan2
- H2AC20 | c.73C>T p.Q25* | Nonsense Mutation (SNP) | VAF 98/221 reads (44%) | catalogued as COSV58612664; called by muse, mutect2, varscan2
- HDAC9 | c.2027A>T p.K676I | Missense Mutation (SNP) | VAF 6/114 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.285); catalogued as rs1476157677; called by muse, mutect2
- HLCS | c.468C>A p.N156K | Missense Mutation (SNP) | VAF 30/70 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.254); catalogued as rs1308450296, COSV60795705; called by muse, mutect2, varscan2
- HUWE1 | c.13039C>A p.L4347M | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99470855; called by muse, mutect2, varscan2
- ICE1 | c.1126G>A p.D376N | Missense Mutation (SNP) | VAF 23/119 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.112); catalogued as COSV56828934; called by muse, mutect2, varscan2
- IFI35 | c.511G>T p.V171F (on ENST00000415816 / NM_001330230.2; = p.V173F on NM_005533.5) | Missense Mutation (SNP) | VAF 111/134 reads (83%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV55896687; called by muse, mutect2, varscan2
- IL18RAP | c.712G>T p.V238F | Missense Mutation (SNP) | VAF 108/276 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs757197083, COSV51827677; called by muse, varscan2
- IL31RA | c.1988A>G p.N663S | Missense Mutation (SNP) | VAF 36/44 reads (82%) | SIFT tolerated (0.08); PolyPhen benign (0.023); catalogued as COSV61695599; called by muse, mutect2, varscan2
- ITGA4 | c.671C>G p.S224C | Missense Mutation (SNP) | VAF 6/88 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as COSV99276419; called by muse, mutect2
- KCNT2 | c.2844T>G p.C948W | Missense Mutation (SNP) | VAF 88/141 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV54080058, COSV54094303; called by muse, mutect2, varscan2
- KIAA1210 | c.1311A>T p.L437F | Missense Mutation (SNP) | VAF 11/109 reads (10%) | SIFT tolerated (0.41); PolyPhen benign (0.031); catalogued as COSV68178641; called by muse, mutect2, varscan2
- LILRA1 | c.337C>T p.P113S | Missense Mutation (SNP) | VAF 28/83 reads (34%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.675); catalogued as rs748102322, COSV52179133, COSV52182929; called by muse, mutect2, varscan2
- LIPK | c.1009A>G p.I337V | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs1319963721, COSV68201538; called by muse, mutect2, varscan2
- MEPE | c.1068C>A p.N356K | Missense Mutation (SNP) | VAF 36/57 reads (63%) | SIFT deleterious (0); PolyPhen possibly damaging (0.759); catalogued as COSV63073481; called by muse, mutect2, varscan2
- MET | c.662A>G p.E221G | Missense Mutation (SNP) | VAF 61/512 reads (12%) | SIFT tolerated (0.75); PolyPhen probably damaging (0.999); catalogued as COSV59265312; called by muse, mutect2, varscan2
- MOCS1 | c.1085A>G p.K362R | Missense Mutation (SNP) | VAF 78/117 reads (67%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.651); catalogued as COSV51368064; called by muse, mutect2, varscan2
- MYH14 | c.3445G>T p.V1149L | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.13); PolyPhen benign (0.005); catalogued as COSV51825121; called by muse, mutect2, varscan2
- MYO10 | c.5228C>T p.A1743V | Missense Mutation (SNP) | VAF 46/114 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.505); catalogued as COSV57025957; called by muse, mutect2, varscan2
- MYO1B | c.2292G>C p.W764C | Missense Mutation (SNP) | VAF 75/155 reads (48%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV58434890; called by muse, mutect2, varscan2
- MYO3A | c.2038A>T p.K680* | Nonsense Mutation (SNP) | VAF 181/456 reads (40%) | catalogued as COSV99780022; called by muse, mutect2, varscan2
- NPBWR1 | c.968C>T p.T323I | Missense Mutation (SNP) | VAF 6/8 reads (75%) | SIFT tolerated (0.13); PolyPhen benign (0.006); catalogued as rs747475610, COSV58697008; called by mutect2, varscan2
- NPPA | c.451T>C p.Y151H | Missense Mutation (SNP) | VAF 28/89 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.556); catalogued as COSV56741834; called by muse, mutect2, varscan2
- NPRL3 | c.1058C>G p.S353C (on ENST00000611875 / NM_001077350.3; = p.S328C on NM_001039476.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.759); catalogued as COSV67853715; called by mutect2, varscan2
- OR10J3 | c.947G>C p.R316T | Missense Mutation (SNP) | VAF 6/174 reads (3%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV59954454; called by muse, mutect2
- PADI3 | c.538A>G p.M180V | Missense Mutation (SNP) | VAF 19/88 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.437); catalogued as rs1174488305, COSV64934894; called by muse, mutect2, varscan2
- PAXBP1 | c.2158T>G p.S720A | Missense Mutation (SNP) | VAF 28/291 reads (10%) | SIFT tolerated (0.16); PolyPhen benign (0.101); catalogued as COSV51610796; called by muse, mutect2
- PHF8 | c.1445A>G p.Q482R (on ENST00000357988 / NM_001184896.1; = p.Q446R on NM_015107.3) | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.024); catalogued as COSV57684871; called by muse, mutect2, varscan2
- PTPN13 | c.7250C>A p.T2417N (on ENST00000411767 / NM_080683.3; = p.T2398N on NM_006264.3) | Missense Mutation (SNP) | VAF 12/88 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57412545; called by muse, mutect2, varscan2
- RAPSN | c.909C>G p.D303E | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT tolerated (0.7); PolyPhen benign (0.001); catalogued as rs376607111; called by muse, mutect2, varscan2
- RASAL2 | c.412G>T p.E138* | Nonsense Mutation (SNP) | VAF 23/90 reads (26%) | catalogued as COSV62718499; called by muse, mutect2, varscan2
- RMI2 | c.373C>T p.L125F | Missense Mutation (SNP) | VAF 167/391 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56964289; called by muse, mutect2, varscan2
- RYR2 | c.2189T>C p.L730P | Missense Mutation (SNP) | VAF 352/660 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63699659; called by muse, mutect2, varscan2
- SLC26A8 | c.2446C>T p.R816W | Missense Mutation (SNP) | VAF 80/217 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.328); catalogued as rs754358341, COSV100839487; called by muse, mutect2, varscan2
- SLCO6A1 | c.180G>T p.R60S | Missense Mutation (SNP) | VAF 87/178 reads (49%) | SIFT deleterious (0.02); PolyPhen benign (0.03); catalogued as COSV65806812; called by muse, mutect2, varscan2
- SPANXN4 | c.271G>T p.G91* | Nonsense Mutation (SNP) | VAF 48/70 reads (69%) | catalogued as COSV65141576; called by muse, mutect2, varscan2
- SULF2 | c.382G>T p.A128S | Missense Mutation (SNP) | VAF 86/197 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.054); catalogued as COSV63418418; called by muse, mutect2, varscan2
- TCN1 | c.363G>T p.K121N | Missense Mutation (SNP) | VAF 34/383 reads (9%) | SIFT tolerated (0.5); PolyPhen benign (0.043); catalogued as COSV57253911; called by muse, mutect2
- TDP1 | c.1187_1193del p.G396Vfs*24 | Frame Shift Del (DEL) | VAF 67/146 reads (46%) | catalogued as COSV59644625; called by mutect2, pindel, varscan2
- TEAD3 | c.90T>G p.D30E | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0.078); catalogued as COSV58817651; called by muse, mutect2, varscan2
- TGM2 | c.931C>G p.L311V | Missense Mutation (SNP) | VAF 14/204 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as COSV100821654; called by muse, mutect2
- THAP9 | c.2327A>T p.E776V | Missense Mutation (SNP) | VAF 14/84 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV56357106; called by muse, mutect2, varscan2
- TKTL2 | c.1340G>T p.C447F | Missense Mutation (SNP) | VAF 99/127 reads (78%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as COSV54919865, COSV54920168; called by muse, mutect2, varscan2
- TMEM45A | c.706G>A p.V236I | Missense Mutation (SNP) | VAF 512/1471 reads (35%) | SIFT tolerated (0.68); PolyPhen benign (0.005); catalogued as rs765084110, COSV100058282; called by muse, mutect2, varscan2
- TYR | c.1172C>T p.A391V | Missense Mutation (SNP) | VAF 101/282 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.492); catalogued as CM033059, COSV54475515; called by muse, mutect2, varscan2
- UBQLNL | c.1361A>C p.E454A | Missense Mutation (SNP) | VAF 16/272 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.476); catalogued as COSV100974532; called by muse, mutect2
- UGT1A10 | c.655T>C p.F219L | Missense Mutation (SNP) | VAF 581/1250 reads (46%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV60845661; called by muse, mutect2, varscan2
- UNC13B | c.841C>T p.H281Y | Missense Mutation (SNP) | VAF 42/377 reads (11%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.031); catalogued as COSV65936821; called by muse, mutect2, varscan2
- VPS16 | c.2216A>G p.D739G | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.446); catalogued as COSV66791823, COSV66797027; called by muse, mutect2, varscan2
- ZNF765 | c.1522A>T p.N508Y | Missense Mutation (SNP) | VAF 34/66 reads (52%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV67182976; called by muse, mutect2, varscan2
- ATG2A | c.5817_*26del | Nonstop Mutation (DEL) | VAF 8/47 reads (17%) | called by mutect2, pindel
- ATG2B | c.2737-4_2737-3dup | Splice Region (INS) | VAF 80/232 reads (34%) | called by mutect2, pindel, varscan2
- COASY | c.1133del p.L378Rfs*49 | Frame Shift Del (DEL) | VAF 3/35 reads (9%) | called by mutect2, pindel
- DDX18 | c.1479A>T p.E493D | Missense Mutation (SNP) | VAF 21/377 reads (6%) | SIFT tolerated (0.35); PolyPhen benign (0.018); called by muse, mutect2
- EIF4G2 | c.731T>A p.L244H | Missense Mutation (SNP) | VAF 12/197 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2
- GXYLT1 | c.715del p.T239Hfs*15 | Frame Shift Del (DEL) | VAF 74/223 reads (33%) | called by mutect2, pindel*, varscan2
- HECTD1 | c.7375C>A p.Q2459K | Missense Mutation (SNP) | VAF 94/243 reads (39%) | SIFT tolerated (0.88); PolyPhen benign (0.061); called by mutect2, varscan2
- HMBS | c.34-23_37del p.X12_splice | Splice Site (DEL) | VAF 10/18 reads (56%) | called by mutect2, varscan2
- IL21R | c.325_350del p.C109Hfs*18 | Frame Shift Del (DEL) | VAF 18/39 reads (46%) | called by mutect2, pindel
- INPP4B | c.733_735del p.D245del | In Frame Del (DEL) | VAF 20/72 reads (28%) | called by mutect2, pindel*, varscan2
- LAIR1 | c.724_737delinsCA p.A242_S246delinsH | In Frame Del (DEL) | VAF 8/59 reads (14%) | called by pindel, varscan2*
- PFKP | c.1351G>C p.D451H | Missense Mutation (SNP) | VAF 4/41 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); called by muse, mutect2
- PNP | c.90_91del p.I30Mfs*10 | Frame Shift Del (DEL) | VAF 124/328 reads (38%) | called by mutect2, pindel, varscan2
- RIMBP2 | c.2811_2821+18del p.X937_splice | Splice Site (DEL) | VAF 29/56 reads (52%) | called by mutect2, pindel
- SRGAP3 | c.2411_2420del p.D804Afs*5 | Frame Shift Del (DEL) | VAF 14/65 reads (22%) | called by mutect2, pindel, varscan2
- TRIM75P | c.353T>G p.L118R | Missense Mutation (SNP) | VAF 12/182 reads (7%) | SIFT tolerated (0.38); PolyPhen benign (0.059); called by muse, mutect2
- TSC1 | c.2162_2172del p.R721Qfs*9 | Frame Shift Del (DEL) | VAF 14/30 reads (47%) | called by mutect2, pindel, varscan2
- UQCRC1 | c.222G>T p.W74C | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- UQCRC1 | c.221G>T p.W74L | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.837); called by muse, mutect2, varscan2
- VN1R5 | c.646G>C p.V216L | Missense Mutation (SNP) | VAF 687/1272 reads (54%) | SIFT tolerated (0.85); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- YLPM1 | c.3248_3251del p.L1083* | Frame Shift Del (DEL) | VAF 51/130 reads (39%) | called by mutect2, pindel, varscan2
- ABCF3 | c.1599C>G p.T533= | Silent (SNP) | VAF 15/40 reads (38%) | catalogued as COSV53053694; called by muse, mutect2, varscan2
- ACAT1 | c.783T>C p.F261= | Silent (SNP) | VAF 45/58 reads (78%) | catalogued as COSV54921674; called by muse, varscan2
- AKAP6 | c.1323G>A p.L441= | Silent (SNP) | VAF 378/892 reads (42%) | catalogued as COSV55215909; called by muse, mutect2, varscan2
- CD109 | c.3340A>C p.R1114= | Silent (SNP) | VAF 67/243 reads (28%) | catalogued as COSV54653401, COSV99754807; called by muse, mutect2, varscan2
- CD5 | c.318C>A p.I106= | Silent (SNP) | VAF 15/216 reads (7%) | called by muse, mutect2
- EEFSEC | c.903G>T p.G301= | Silent (SNP) | VAF 25/104 reads (24%) | catalogued as COSV54629198; called by muse, mutect2, varscan2
- ERCC4 | c.2340C>T p.S780= | Silent (SNP) | VAF 82/793 reads (10%) | catalogued as COSV61313101; called by muse, mutect2, varscan2
- FAT4 | c.4359T>A p.G1453= | Silent (SNP) | VAF 130/185 reads (70%) | catalogued as COSV67893923; called by muse, mutect2, varscan2
- FGF14 | c.523T>C p.L175= | Silent (SNP) | VAF 109/140 reads (78%) | catalogued as COSV65950768; called by muse, mutect2, varscan2
- KIF3C | c.1335C>A p.P445= | Silent (SNP) | VAF 30/41 reads (73%) | catalogued as COSV53100798; called by muse, mutect2, varscan2
- MAGED1 | c.855G>A p.Q285= | Silent (SNP) | VAF 20/28 reads (71%) | catalogued as COSV58516081; called by muse, mutect2, varscan2
- OR8H1 | c.669C>A p.T223= | Silent (SNP) | VAF 126/329 reads (38%) | catalogued as COSV57295025; called by muse, mutect2, varscan2
- PCDHB7 | c.2157G>T p.P719= | Silent (SNP) | VAF 8/120 reads (7%) | called by muse, mutect2
- PPEF2 | c.9C>T p.S3= | Silent (SNP) | VAF 107/276 reads (39%) | catalogued as rs367898608, COSV54422289; called by muse, mutect2, varscan2
- RYR3 | c.1827G>T p.G609= | Silent (SNP) | VAF 11/43 reads (26%) | catalogued as COSV66801239; called by muse, mutect2, varscan2
- SAP30 | c.300C>A p.I100= | Silent (SNP) | VAF 7/38 reads (18%) | catalogued as rs750924784, COSV56634976; called by muse, mutect2, varscan2
- SLC6A1 | c.366C>T p.F122= | Silent (SNP) | VAF 33/90 reads (37%) | catalogued as COSV55117152; called by muse, mutect2, varscan2
- SURF6 | c.429G>A p.E143= | Silent (SNP) | VAF 7/40 reads (18%) | catalogued as COSV64395681; called by muse, mutect2, varscan2
- ZNF772 | c.1308C>T p.C436= | Silent (SNP) | VAF 77/186 reads (41%) | catalogued as COSV100582849; called by muse, mutect2, varscan2
- DPP6 | c.627+20900A>G | Intron (SNP) | VAF 24/60 reads (40%) | catalogued as rs1445021845; called by muse, varscan2
- GRM8 | c.727+48341G>A | Intron (SNP) | VAF 13/98 reads (13%) | catalogued as rs1478058234, COSV58884665; called by muse, mutect2
- MTRNR2L6 | chr7:142671120 A>G | 3'Flank (SNP) | VAF 158/506 reads (31%) | called by muse, mutect2, varscan2
